Somatic mutation profile of tumor specimen TCGA-CM-4751-01A (aliquot TCGA-CM-4751-01A-02D-1835-10) from TCGA case TCGA-CM-4751, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 62.7 years (22,891 days).
Specimen TCGA-CM-4751-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 975fa153-bdd8-4bad-a012-14cedc6207df.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CM-4751-10A (Blood Derived Normal), aliquot TCGA-CM-4751-10A-01D-1835-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d23ed6b2-08f0-4c4f-90f9-1d6c447d8746

The open-access MAF lists 97 somatic variants for this specimen: 74 protein-altering or splice-affecting, 21 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 21, Nonsense Mutation 3, Frame Shift Ins 2, Intron 1, 3'UTR 1, Splice Site 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 47/201 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 64/281 reads (23%) | hotspot (GDC flag); SIFT tolerated (0.36); PolyPhen benign (0.396); catalogued as rs867262025, CM126693, COSV55875460; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 10/31 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs193920774, CM1414506, COSV52664019, COSV52666760, COSV53585299; ClinVar: pathogenic / likely pathogenic / uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ABCA13 | c.8316G>T p.L2772F | Missense Mutation (SNP) | VAF 56/272 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as COSV101446905; called by muse, mutect2, varscan2
- ABCC12 | c.2945T>C p.V982A | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as COSV100252492; called by muse, mutect2, varscan2
- ACOXL | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs201574685; called by muse, mutect2, varscan2
- ADGRA1 | c.1355G>A p.R452H | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs554931104, COSV66926322; called by muse, mutect2, varscan2
- ADGRB1 | c.3562C>T p.R1188C | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs752785041, COSV100029884, COSV60096304; called by muse, mutect2
- AUTS2 | c.2392C>T p.R798* | Nonsense Mutation (SNP) | VAF 20/76 reads (26%) | catalogued as COSV100716094, COSV61392954; called by muse, mutect2, varscan2
- CALD1 | c.1555G>A p.V519M (on ENST00000361675 / NM_033138.4; = p.V264M on NM_004342.7) | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs569578471, COSV62645190; called by muse, mutect2, varscan2
- CCDC88C | c.3806A>G p.K1269R | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as COSV66239492; called by muse, mutect2, varscan2
- CEP83 | c.1064A>G p.N355S | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.046); catalogued as rs1566001244, COSV100352784; called by muse, mutect2, varscan2
- CHKB | c.961A>G p.K321E | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs143218928; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLEC18A | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 91/346 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs144325555; called by muse, mutect2, varscan2
- CYP4F3 | c.610C>A p.Q204K | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.821); catalogued as COSV99658052; called by muse, mutect2, varscan2
- DLGAP3 | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs370097610; called by muse, mutect2, varscan2
- EPM2AIP1 | c.899C>T p.T300I | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.075); catalogued as COSV99212392; called by muse, mutect2, varscan2
- EXOC1 | c.1454G>A p.R485H | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.91); catalogued as rs1281156642, COSV62120369; called by muse, mutect2, varscan2
- FAT1 | c.7667G>A p.R2556Q | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768745435, COSV101499264; called by muse, mutect2, varscan2
- FLT3 | c.931C>T p.R311W | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54057282; called by muse, mutect2, varscan2
- FOSL1 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs779143676, COSV57028381; called by muse, mutect2
- GLG1 | c.1964A>G p.Q655R | Missense Mutation (SNP) | VAF 51/216 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as COSV99215603; called by muse, mutect2, varscan2
- GPR158 | c.2260A>G p.I754V | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as COSV100893233, COSV100894400; called by muse, mutect2, varscan2
- GPR50 | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.205); catalogued as rs900102278, COSV54440920, COSV99505940; called by muse, mutect2, varscan2
- GRIA2 | c.1433C>T p.T478M | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs778623018, COSV99643923; called by muse, mutect2, varscan2
- H4C11 | c.96G>C p.K32N | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as rs1437362486, COSV100747979; called by muse, mutect2, varscan2
- HTR2C | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs371347099, COSV52210409, COSV99348797; called by muse, mutect2, varscan2
- IGHA2 | c.627C>T p.S209= | Splice Region (SNP) | VAF 20/91 reads (22%) | catalogued as rs1240882882; called by muse, mutect2, varscan2
- IGKV3-15 | c.53C>T p.T18I | Missense Mutation (SNP) | VAF 39/326 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs559425238; called by muse, mutect2, varscan2
- ITSN1 | c.4858T>C p.Y1620H | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101181644; called by muse, mutect2, varscan2
- JADE1 | c.1181G>A p.R394Q | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs763437009, COSV99885615; called by muse, mutect2, varscan2
- KCNV1 | c.462A>T p.R154S | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.177); catalogued as COSV99819004; called by muse, mutect2
- KLC1 | c.987+1G>C p.X329_splice | Splice Site (SNP) | VAF 4/28 reads (14%) | catalogued as COSV99871391; called by muse, mutect2
- KLHL11 | c.1642T>G p.F548V | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100044276; called by muse, mutect2, varscan2
- KMT2B | c.4460G>A p.R1487H | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs753899619, COSV99719287; called by muse, mutect2
- MEP1A | c.526G>A p.V176M | Missense Mutation (SNP) | VAF 39/197 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100042566; called by muse, mutect2, varscan2
- MGAT4C | c.1396G>T p.E466* | Nonsense Mutation (SNP) | VAF 39/201 reads (19%) | catalogued as COSV100152833; called by muse, varscan2
- MLPH | c.1075G>T p.E359* | Nonsense Mutation (SNP) | VAF 23/126 reads (18%) | catalogued as COSV99222105; called by muse, mutect2, varscan2
- MMP11 | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs563846943, COSV99303157; called by muse, mutect2, varscan2
- MPP4 | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs191664251, COSV59630604; called by muse, mutect2, varscan2
- MYORG | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.823); catalogued as COSV52627680; called by muse, mutect2, varscan2
- MYT1L | c.1885C>T p.R629C | Missense Mutation (SNP) | VAF 72/236 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs778495328, COSV67724039; called by muse, mutect2, varscan2
- NAALADL1 | c.1465C>T p.R489W | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV100367975, COSV100368014; called by muse, mutect2, varscan2
- NOVA1 | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99947156; called by muse, mutect2, varscan2
- NUTM2D | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs780066522, COSV67746657; called by muse, mutect2, varscan2
- OR1Q1 | c.829G>A p.V277M | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs777771498, COSV52918393; called by muse, mutect2, varscan2
- OR52N2 | c.8G>C p.G3A | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV100396089, COSV57678117; called by muse, mutect2, varscan2
- PAK1 | c.935T>G p.I312S | Missense Mutation (SNP) | VAF 30/177 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53694809, COSV53695351; called by muse, mutect2, varscan2
- PKD1L1 | c.469C>T p.R157W | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs547737514, COSV56962166; called by muse, mutect2, varscan2
- PRB3 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.068); catalogued as rs535647192, COSV54389175, COSV54391593; called by muse, varscan2
- PRTN3 | c.195C>G p.F65L | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99311504; called by muse, mutect2
- RHBDF2 | c.1648C>T p.H550Y | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.493); catalogued as COSV99166199; called by muse, mutect2, varscan2
- RNF43 | c.1660C>G p.R554G | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.894); catalogued as COSV68457761; called by muse, mutect2, varscan2
- SALL1 | c.3685G>A p.D1229N | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201147024; called by muse, mutect2, varscan2
- SLC37A3 | c.1365G>A p.M455I (on ENST00000326232 / NM_001363375.1; = p.V355M on NM_032295.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/197 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100405393; called by muse, mutect2, varscan2
- SLC6A2 | c.1066G>A p.V356I | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs5565, COSV54922904; called by muse, mutect2, varscan2
- SLK | c.1943C>T p.T648I | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs544458791, COSV100211668; called by muse, mutect2, varscan2
- SPATA16 | c.57T>A p.D19E | Missense Mutation (SNP) | VAF 53/254 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as COSV100651096; called by muse, mutect2, varscan2
- STARD13 | c.2636G>A p.R879H (on ENST00000336934 / NM_001243476.3; = p.R761H on NM_052851.3) | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs374830984; called by muse, varscan2
- SVOPL | c.1283G>A p.R428H (on ENST00000419765; = p.R276H on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as rs1287870402, COSV55988704; called by muse, mutect2, varscan2
- TAF1A | c.1187A>G p.D396G | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.592); catalogued as rs1442836275, COSV100600962; called by muse, mutect2, varscan2
- TBC1D9 | c.2594G>A p.R865H | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.348); catalogued as rs753790959, COSV71307950; called by muse, mutect2, varscan2
- TRIM42 | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as rs1432924023, COSV53880010, COSV53884987; called by muse, mutect2, varscan2
- TTN | c.32335C>T p.R10779C (on ENST00000591111; = p.R9852C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/78 reads (28%) | PolyPhen benign (0.123); catalogued as rs377710763; called by muse, mutect2, varscan2
- TULP1 | c.1346G>A p.R449H | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57693158; called by muse, mutect2, varscan2
- XKR3 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1430750371, COSV58887357; called by muse, mutect2, varscan2
- XRCC3 | c.172C>T p.R58W | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs143410843; called by muse, mutect2, varscan2
- ZNF285 | c.1669G>T p.A557S | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.668); catalogued as COSV100449949; called by muse, mutect2, varscan2
- ZNF382 | c.1066G>A p.D356N | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as rs766247460, COSV53086561; called by muse, mutect2, varscan2
- ZNF80 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.74); PolyPhen benign (0.026); catalogued as rs144045417, COSV100351990; called by muse, mutect2, varscan2
- AXIN2 | c.873dup p.A292Cfs*10 | Frame Shift Ins (INS) | VAF 21/80 reads (26%) | called by mutect2, pindel, varscan2
- B2M | c.36_62del p.L13_I21del | In Frame Del (DEL) | VAF 6/48 reads (13%) | called by mutect2, pindel
- OBSCN | c.10507T>A p.C3503S | Missense Mutation (SNP) | VAF 56/175 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by mutect2, varscan2
- SOX9 | c.764_765dup p.G256Rfs*24 | Frame Shift Ins (INS) | VAF 26/98 reads (27%) | called by mutect2, pindel, varscan2
- ABRA | c.582C>T p.S194= | Silent (SNP) | VAF 22/129 reads (17%) | catalogued as rs150778049, COSV100357518; called by muse, mutect2, varscan2
- BOC | c.1359G>A p.T453= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as rs377030774; called by muse, mutect2, varscan2
- BPIFB4 | c.756C>T p.Y252= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as rs1415523255, COSV100971482; called by muse, mutect2
- CD47 | c.381C>T p.I127= | Silent (SNP) | VAF 52/237 reads (22%) | catalogued as rs777288181, COSV100790109; called by muse, mutect2, varscan2
- DGCR2 | c.1134C>T p.R378= | Silent (SNP) | VAF 17/100 reads (17%) | catalogued as COSV99593529; called by muse, mutect2, varscan2
- DTNBP1 | c.531C>T p.H177= | Silent (SNP) | VAF 53/124 reads (43%) | catalogued as rs771033313, COSV59042952; called by muse, mutect2, varscan2
- FAM110D | c.45C>T p.P15= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as rs1004905245, COSV100957624; called by muse, mutect2, varscan2
- FCN2 | c.414C>T p.D138= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs768992885, COSV99391214; called by muse, mutect2, varscan2
- GAB4 | c.1302G>A p.P434= | Silent (SNP) | VAF 31/128 reads (24%) | catalogued as rs191430521; called by muse, mutect2, varscan2
- GDNF | c.447C>T p.C149= | Silent (SNP) | VAF 18/95 reads (19%) | catalogued as rs368244196; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCNT1 | c.2139G>A p.S713= (on ENST00000488444; = p.S732= on NM_020822.3) | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs557680361, COSV99705507; ClinVar: likely benign; called by mutect2, varscan2
- NOL4L | c.135C>T p.S45= | Silent (SNP) | VAF 28/112 reads (25%) | catalogued as rs149678556; called by muse, mutect2, varscan2
- OBSCN | c.4182G>A p.S1394= | Silent (SNP) | VAF 49/206 reads (24%) | catalogued as rs765044878, COSV99476133; called by muse, mutect2, varscan2
- PACRGL | c.192T>C p.P64= | Silent (SNP) | VAF 58/226 reads (26%) | catalogued as COSV99764016; called by muse, mutect2, varscan2
- PDZD2 | c.3006G>A p.R1002= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as COSV99224588; called by muse, mutect2, varscan2
- PRRC2C | c.4584G>A p.K1528= (on ENST00000367742; = p.K1526= on NM_015172.4) | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV100145056; called by muse, mutect2, varscan2
- ST6GALNAC4 | c.531C>T p.P177= | Silent (SNP) | VAF 24/130 reads (18%) | catalogued as rs775418382, COSV100231399, COSV100231521; called by muse, mutect2, varscan2
- TRIM62 | c.537C>T p.G179= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as rs781609175, COSV52222507; called by muse, mutect2, varscan2
- UBFD1 | c.402C>T p.P134= | Silent (SNP) | VAF 62/261 reads (24%) | catalogued as rs202219563, COSV54842493, COSV99563318; called by muse, mutect2, varscan2
- ZMYM1 | c.2685A>G p.A895= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV63252513; called by muse, mutect2, varscan2
- ZNF595 | c.504T>C p.T168= | Silent (SNP) | VAF 25/93 reads (27%) | catalogued as COSV100227573; called by muse, mutect2, varscan2
- ANKRD13D | c.*855G>C | 3'UTR (SNP) | VAF 59/181 reads (33%) | catalogued as COSV57385610; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85531G>A | Intron (SNP) | VAF 33/136 reads (24%) | catalogued as COSV72276297; called by muse, mutect2, varscan2
